Gene-level copy-number profile of tumor specimen ALCH-B3G3-TTP1-A from ALCHEMIST case ALCH-B3G3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 73.7 years (26,921 days).
Specimen ALCH-B3G3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 86c6bd1e-e543-4313-aeb0-1941a80c1eee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3G3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/fd11f9ea-070d-48a1-ae20-ad3f50d01f93

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 5,120; copy number 2: 52,952; copy number 3: 748; copy number 4: 13; copy number 5: 3; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr7:6,637,318–6,658,279, 1 gene: ZNF316.
- chr7:56,991,888–57,020,273, 2 genes: TNRC18P3, SLC29A4P1.
- chr7:63,768,257–63,771,047, 1 gene: CICP24.
- chr7:149,776,042–149,833,979, 1 gene: SSPOP.
- chr9:134,317,098–134,440,585, 2 genes: RXRA, MIR4669.
- chr11:612,553–615,983, 1 gene: IRF7.
- chr14:104,085,686–104,180,894, 5 genes: ASPG, MIR203A, MIR203B, AL359399.1, KIF26A.
- chr15:25,169,337–25,225,284, 31 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:88,382,959–88,440,757, 1 gene: ZNF469.
- chr16:88,468,918–88,469,031, 1 gene (within-gene range 0–1): MIR5189.
- chr17:81,976,807–82,098,294, 11 genes: ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN.
- chr21:44,300,051–44,330,221, 2 genes (within-gene range 0–2): PFKL, AP001062.3.
- chr22:46,006,616–46,010,777, 1 gene: BX537318.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,113,639–1,132,977, 1 gene, copy number 6 (within-gene range 2–6): AC092535.4.
- chr4:1,118,884–1,119,013, 1 gene, copy number 6 (within-gene range 2–6): AC092535.1.
- chr8:42,541,155–42,555,195, 1 gene, copy number 5 (within-gene range 2–5): SMIM19.
- chr18:35,972,151–35,979,286, 2 genes, copy number 5: AC091060.1, C18orf21.

Autosomal genes at a single copy (total copy number 1): 2,275. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
